Somatic mutation profile of tumor specimen MP2PRT-PAWCSX-TMP1-A (aliquot MP2PRT-PAWCSX-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWCSX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,057 days).
Specimen MP2PRT-PAWCSX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 149239a0-0ea8-44c9-b2d8-970a6f7622a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCSX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCSX-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/119ff8e8-6d3e-48bc-91e6-235639d2e2e6

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 74/267 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 116/319 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRT73 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 135/432 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs761352447; called by muse, mutect2, varscan2
- PLCE1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs796709138, COSV99598056; called by muse, mutect2, varscan2
- PLXNA2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 134/353 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65437548; called by muse, mutect2, varscan2
- WSCD1 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs773583789, COSV100496779; called by muse, mutect2, varscan2
- KMT2C | c.9502G>A p.G3168S | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VN1R1 | c.916A>C p.I306L | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARC | c.453C>T p.G151= | Silent (SNP) | VAF 202/757 reads (27%) | catalogued as rs754111376, COSV63078654; called by muse, mutect2, varscan2
- KRTAP19-3 | c.228A>G p.G76= | Silent (SNP) | VAF 74/419 reads (18%) | called by muse, mutect2, varscan2
- TLR5 | c.2262C>T p.I754= | Silent (SNP) | VAF 106/310 reads (34%) | catalogued as rs780943112, COSV60557822, COSV60559477; called by muse, mutect2
- UNC79 | c.4887C>T p.S1629= (on ENST00000393151 / NM_001346218.2; = p.S1452= on NM_020818.5) | Silent (SNP) | VAF 132/624 reads (21%) | catalogued as rs781387821, COSV56377182; called by muse, mutect2, varscan2
- MYC | c.-549G>T | 5'UTR (SNP) | VAF 232/792 reads (29%) | called by muse, mutect2, varscan2
